Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3869, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3869-01A (Primary Tumor).

Diagnosis

Resected ileocolic sample with an ulcerated, moderately differentiated adenocarcinoma of the colorectal type, measuring max. 7 cm in diameter, covering the cecum extensively, with broad infiltration of the pericecal fatty tissue, circumscribed penetration of the covering serosa and 14 local lymph node metastases. Tumor-free small and large intestine resection margins. Tumor-free mesenteric resection margin. Tumor-free appendix.

The tumor stage is pT4 pN2 (14/28) pM1 (clinical liver metastases); G2 L1, V0, R2

Source: NCI Genomic Data Commons file 25dae3a9-a474-4c92-b1ad-1819e972683f (TCGA-AA-3869.34C6F392-82CD-449E-928E-16C5551FAEA8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).